Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6295, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6295-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON TERMINAL ILEUM

DIAGNOSIS:

RIGHT COLON AND TERMINAL ILEUM, ILEOCOLECTOMY:

- 1) INFILTRATING POORLY DIFFERENTIATED ADENOCARCINOMA OF COLON WITH MEDULLARY FEATURES INVADING THROUGH MUSCULARIS PROPRIA INTO SUBSerosA.
- TUMOR SIZE: 7x5x1.2 CM.
- MARGINS OF RESECTION, NO TUMOR SEEN.
- TWENTY THREE LYMPH NODES, NEGATIVE FOR METASTASIS (0/23)
- 2) MULTIPLE TUBULAR ADENOMAS AND HYPERPLASTIC POLYPS OF ASCENDING COLON

COLORECTAL CANCER TEMPLATE

Tumor Size (cm):	7x5x1.2 cm.
Histologic Type:	Adenocarcinoma
Grade/Differentiation:	Grade 3 with medullary features
Invasion Depth:	Subserosa
Invasion Vasc/Lymphatic:	Absent
Invasion Perineural:	Absent
Extension to Adj. Areas:	NA
Margins:	Free
Lymph Nodes:	Negative (0/23)
Stage Pathology:	pT3N0 MX
Implants:	Absent
Precursor:	Present, tubular adenomas and hyperplastic polyps
Non-neoplastic areas:	NA

SPECIMEN(S):

A. RIGHT COLON TERMINAL ILEUM

CLINICAL HISTORY:

NA

GROSS DESCRIPTION:

A. RIGHT COLON, TERMINAL ILEUM

Received fresh and subsequently fixed with matching patient name and requisition number is a 30cm right hemicolectomy specimen consisting of a 5cm in length, 2cm in circumference terminal ileum segment and 25cm in length, 6cm average circumference right colon with moderate amount of pericolonic fat and surgically absent appendix. There is a 7x5x1.2cm light tan fungating tumor mass located in the proximal cecum, 2.5cm from the ileocecal valve, 7cm from the proximal and 17cm from the distal margin. Cut section of the tumor shows it is penetrating the muscularis propria and focally extending into the subserosal fat. Tumor tissue has been procured. There are multiple flat sessile polypoid lesions scattered in the right colon, ranging from 0.2cm in greatest dimension to 1.0x0.7x0.5cm. The most distal one is more than 1cm away from the distal surgical margin. The uninvolved colonic mucosa as well as the terminal ileum have kept its normal rugosity and are grossly unremarkable. The mesenteric fat is thoroughly dissected and all lymph nodes are submitted for microscopic examination. Representative sections are taken as follows:

- A1-A7: representatives of the tumor
- A8: three polypoid lesions
- A9: one polypoid lesion, bisected
- A10-A11: one polypoid lesion, serially sectioned
- A12: four polypoid lesions
- A13: the most distal polyp
- A14: representatives of the uninvolved colonic mucosa
- A15: distal surgical margin
- A16: proximal surgical margin and uninvolved terminal ileum
- A17: 6 presumptive lymph nodes
- A18: 2 bisected lymph nodes, one inked black
- A19: 2 lymph nodes, larger one bisected
- A20: 2 bisected lymph nodes, one is black

[page 2 of 2]
A21: 2 bisected lymph nodes, larger is grossly positive
A22: 1 lymph node, serially sectioned
A23: 3 presumptive lymph nodes
A24: 1 bisected lymph node
A25: 1 bisected lymph node
A26: 2 bisected lymph nodes, 1 inked black
A27: 2 lymph nodes

Source: NCI Genomic Data Commons file e7c1849a-bc75-4b53-9322-0f155cc31905 (TCGA-G4-6295.C154D187-5C39-4C08-A525-7DC34B810450.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).